Somatic mutation profile of tumor specimen MMRF_1952_1_BM_CD138pos (aliquot MMRF_1952_1_BM_CD138pos_T1_KBS5U_L06435) from MMRF case MMRF_1952, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: female; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 65.6 years (23,951 days).
Specimen MMRF_1952_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b1592c59-0ce4-4fff-bba5-822a1d6c0cab.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_1952_1_PB_Whole (Blood Derived Normal), aliquot MMRF_1952_1_PB_Whole_C3_KBS5U_L06480; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/323bd965-625e-460f-9333-cba1f86d71a4

The open-access MAF lists 55 somatic variants for this specimen: 19 protein-altering or splice-affecting, 6 silent, 30 other (UTR, intronic, flanking, RNA and similar).
By variant classification: 3'UTR 16, Missense Mutation 15, Intron 9, Silent 6, 3'Flank 2, 5'UTR 2, Splice Region 1, Splice Site 1, Frame Shift Ins 1, Frame Shift Del 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.38G>A p.G13D | Missense Mutation (SNP) | VAF 104/231 reads (45%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen benign (0.44); catalogued as rs112445441, CM125166, COSV55497357, COSV55497388, COSV55522580; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- AXL | c.163C>T p.R55W | Missense Mutation (SNP) | VAF 9/295 reads (3%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as COSV56568572; called by muse, mutect2
- BAHCC1 | c.1996G>A p.E666K | Missense Mutation (SNP) | VAF 37/167 reads (22%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.543); catalogued as rs1555653279; called by muse, mutect2, varscan2
- CELSR1 | c.6934C>T p.R2312C | Missense Mutation (SNP) | VAF 73/180 reads (41%) | SIFT deleterious (0.04); PolyPhen benign (0.396); catalogued as rs1004377573, COSV53098798; called by muse, mutect2, varscan2
- CFHR5 | c.577G>T p.G193W | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1215671777; called by muse, mutect2, varscan2
- CTAG2 | c.124G>A p.G42S | Missense Mutation (SNP) | VAF 16/46 reads (35%) | SIFT tolerated, low confidence (0.44); PolyPhen benign (0.011); catalogued as rs782177344; called by muse, mutect2
- HEPACAM | c.299G>A p.R100Q | Missense Mutation (SNP) | VAF 91/338 reads (27%) | SIFT tolerated (0.66); PolyPhen benign (0.023); catalogued as rs775135709, COSV53428426; called by muse, mutect2, varscan2
- HKDC1 | c.1193G>A p.R398Q | Missense Mutation (SNP) | VAF 90/197 reads (46%) | SIFT tolerated (0.36); PolyPhen benign (0.074); catalogued as rs746771373, COSV100664711, COSV63579436; called by muse, mutect2, varscan2
- LIPF | c.415del p.A139Lfs*20 | Frame Shift Del (DEL) | VAF 8/26 reads (31%) | catalogued as COSV53283560; called by mutect2, pindel, varscan2
- MEPE | c.899dup p.P301Afs*4 | Frame Shift Ins (INS) | VAF 68/185 reads (37%) | catalogued as rs775965129; called by mutect2, pindel, varscan2
- UBQLNL | c.862C>T p.P288S | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT tolerated (0.71); PolyPhen benign (0.087); catalogued as COSV66492553; called by muse, varscan2
- USH2A | c.11050G>T p.V3684F | Missense Mutation (SNP) | VAF 42/118 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1387227775; called by muse, mutect2, varscan2
- CCDC158 | c.1830+1G>T p.X610_splice | Splice Site (SNP) | VAF 8/16 reads (50%) | called by muse, mutect2
- CKAP5 | c.1147G>A p.E383K | Missense Mutation (SNP) | VAF 22/31 reads (71%) | SIFT deleterious (0); PolyPhen possibly damaging (0.694); called by muse, mutect2, varscan2
- CMYA5 | c.7499C>T p.S2500F | Missense Mutation (SNP) | VAF 18/76 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- LRP1 | c.5214C>A p.F1738L | Missense Mutation (SNP) | VAF 93/179 reads (52%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.931); called by muse, mutect2, varscan2
- NUP210P1 | n.140G>A | Splice Region (SNP) | VAF 60/144 reads (42%) | called by muse, mutect2, varscan2
- SLC22A8 | c.1032G>T p.L344F | Missense Mutation (SNP) | VAF 82/151 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- TTYH2 | c.34T>C p.W12R | Missense Mutation (SNP) | VAF 46/97 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- FREM2 | c.8874A>T p.P2958= | Silent (SNP) | VAF 11/27 reads (41%) | called by muse, mutect2, varscan2
- IGHV2-70D | c.327G>A p.V109= | Silent (SNP) | VAF 20/46 reads (43%) | called by muse, varscan2
- IGKJ4 | c.30G>A p.E10= | Silent (SNP) | VAF 10/16 reads (63%) | catalogued as rs180910647; called by muse, varscan2
- KRTAP12-4 | c.291C>A p.P97= | Silent (SNP) | VAF 46/159 reads (29%) | called by muse, mutect2, varscan2
- SH3TC2 | c.1920C>T p.I640= | Silent (SNP) | VAF 10/206 reads (5%) | called by muse, mutect2
- SOBP | c.1722C>T p.G574= | Silent (SNP) | VAF 12/262 reads (5%) | catalogued as rs1209297879, COSV57996428; called by muse, mutect2
- ADNP2 | c.*30A>T | 3'UTR (SNP) | VAF 14/30 reads (47%) | called by muse, mutect2, varscan2
- ARPC1B | c.1081-88C>G | Intron (SNP) | VAF 40/80 reads (50%) | called by muse, mutect2, varscan2
- CDON | c.*1310dup | 3'UTR (INS) | VAF 32/68 reads (47%) | catalogued as rs886047972; ClinVar: uncertain significance; called by mutect2, varscan2
- CNGB3 | chr8:86569360 C>T | 3'Flank (SNP) | VAF 28/70 reads (40%) | called by muse, mutect2, varscan2
- DNM3 | chr1:172412544 T>G | 3'Flank (SNP) | VAF 11/21 reads (52%) | called by muse, mutect2, varscan2
- EIF4E | c.-640_-625delinsC | 5'UTR (DEL) | VAF 41/94 reads (44%) | called by pindel, varscan2*
- FAM114A2 | c.1330-61G>A | Intron (SNP) | VAF 6/9 reads (67%) | catalogued as rs922346344; called by muse, mutect2, varscan2
- FUCA2 | c.1263+251T>A | Intron (SNP) | VAF 11/19 reads (58%) | catalogued as rs1562662940, COSV50020020; called by muse, mutect2, varscan2
- GPX8 | c.*192del | 3'UTR (DEL) | VAF 12/40 reads (30%) | catalogued as rs1023996687; called by mutect2, varscan2
- JCAD | c.*4031G>T | 3'UTR (SNP) | VAF 17/27 reads (63%) | called by muse, mutect2, varscan2
- MCTP2 | c.969+938T>G | Intron (SNP) | VAF 3/10 reads (30%) | catalogued as rs932463662; called by muse, mutect2
- MPV17L | c.*1151G>A | 3'UTR (SNP) | VAF 5/54 reads (9%) | called by muse, mutect2, varscan2
- MTAP | c.813+3839A>C | Intron (SNP) | VAF 4/10 reads (40%) | called by muse, mutect2, varscan2
- MYO9A | c.*740T>A | 3'UTR (SNP) | VAF 36/102 reads (35%) | called by muse, mutect2, varscan2
- NFATC2 | c.*3996C>T | 3'UTR (SNP) | VAF 13/33 reads (39%) | called by muse, mutect2, varscan2
- NTRK2 | c.1397-54494T>A | Intron (SNP) | VAF 6/22 reads (27%) | called by muse, mutect2, varscan2
- PIPSL | n.454C>T | RNA (SNP) | VAF 86/175 reads (49%) | catalogued as rs756748645; called by muse, mutect2, varscan2
- PPARGC1B | c.*713G>A | 3'UTR (SNP) | VAF 19/64 reads (30%) | called by muse, mutect2, varscan2
- PYGB | c.*219G>A | 3'UTR (SNP) | VAF 86/193 reads (45%) | called by muse, mutect2, varscan2
- RUNX1 | c.-124dup | 5'UTR (INS) | VAF 22/92 reads (24%) | catalogued as rs1038183244; called by mutect2, pindel, varscan2
- SIX4 | c.*748_*752del | 3'UTR (DEL) | VAF 21/53 reads (40%) | catalogued as rs569594189; called by mutect2, pindel, varscan2
- SNTN | c.*2956C>T | 3'UTR (SNP) | VAF 9/19 reads (47%) | called by muse, mutect2, varscan2
- SNX14 | c.*250A>G | 3'UTR (SNP) | VAF 4/13 reads (31%) | called by muse, mutect2, varscan2
- SPTSSB | c.*136C>T | 3'UTR (SNP) | VAF 26/51 reads (51%) | called by muse, mutect2, varscan2
- TECPR1 | c.*84G>A | 3'UTR (SNP) | VAF 92/178 reads (52%) | catalogued as rs575178302; called by muse, mutect2, varscan2
- TLCD5 | c.*346T>C | 3'UTR (SNP) | VAF 106/169 reads (63%) | called by muse, mutect2, varscan2
- TMEM132A | c.1559+148G>A | Intron (SNP) | VAF 3/25 reads (12%) | catalogued as rs1227688668; called by muse, mutect2
- TRPC5 | c.*1786G>A | 3'UTR (SNP) | VAF 6/14 reads (43%) | catalogued as rs992742322; called by muse, mutect2, varscan2
- TRPM6 | c.33+107T>A | Intron (SNP) | VAF 50/167 reads (30%) | called by muse, mutect2, varscan2
- WFDC1 | c.421+112C>T | Intron (SNP) | VAF 9/20 reads (45%) | called by muse, varscan2
